Somatic mutation profile of tumor specimen TCGA-19-2624-01A (aliquot TCGA-19-2624-01A-01W-0922-08) from TCGA case TCGA-19-2624, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.7 years (18,891 days).
Specimen TCGA-19-2624-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e562c2ae-04fc-4dbb-b151-7f4e61aea75d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-2624-10A (Blood Derived Normal), aliquot TCGA-19-2624-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b49b766f-5865-4715-a1e2-c513f9e45c81

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 7, Frame Shift Ins 6, Intron 2, Nonsense Mutation 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATXN2 | c.3478C>T p.Q1160* (on ENST00000550104; = p.Q1000* on NM_002973.4) | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV66482503; called by muse, mutect2, varscan2
- CCZ1 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 32/202 reads (16%) | catalogued as rs774988588, COSV58075690; called by muse, mutect2
- CHD3 | c.1618dup p.R540Pfs*47 | Frame Shift Ins (INS) | VAF 14/98 reads (14%) | catalogued as rs747299117; called by mutect2, varscan2
- CSDE1 | c.1310C>G p.T437S (on ENST00000358528 / NM_001007553.3; = p.T406S on NM_007158.6) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.026); catalogued as COSV54743507, COSV99795359; called by muse, mutect2, varscan2
- CYP46A1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381511659, COSV55893974; called by muse, mutect2, varscan2
- DCUN1D5 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.244); catalogued as rs866198680; called by muse, varscan2
- EGFR | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 56/1434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51775191, COSV51835541; called by muse, mutect2
- EGFR | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 53/1410 reads (4%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.997); catalogued as COSV51865283; called by muse, mutect2
- F11R | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.221); catalogued as rs144844671, COSV57036882; called by muse, mutect2, varscan2
- FOXJ2 | c.1270A>G p.S424G | Missense Mutation (SNP) | VAF 115/273 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV50818062; called by muse, mutect2, varscan2
- FZD10 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs1566096577, COSV57472117; called by muse, mutect2, varscan2
- KCTD18 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.253); catalogued as rs763515598, COSV63344131; called by muse, mutect2, varscan2
- KIAA2013 | c.1380dup p.L461Afs*120 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs1272352286; called by pindel, varscan2
- KRTAP6-1 | c.169T>A p.C57S | Missense Mutation (SNP) | VAF 29/169 reads (17%) | PolyPhen benign (0.031); catalogued as COSV58169020; called by muse, mutect2, varscan2
- LHFPL3 | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV67821335; called by muse, mutect2, varscan2
- MAGEB18 | c.208A>G p.T70A | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV57463701; called by muse, mutect2, varscan2
- MYH9 | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs569649580, COSV53393946; called by muse, mutect2, varscan2
- NMUR2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as rs756384094, COSV54918385; called by muse, mutect2, varscan2
- OR51E2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138231892, COSV101211403; called by muse, mutect2
- OR52N4 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 120/243 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as rs574734485, COSV57890742; called by muse, mutect2, varscan2
- OR8I2 | c.516C>A p.S172R | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56167382, COSV56171043; called by muse, mutect2, varscan2
- PLCXD3 | c.839T>A p.V280D | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV60607400; called by muse, mutect2, varscan2
- PLEKHG2 | c.2278G>A p.A760T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV52681207; called by muse, mutect2, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 14/100 reads (14%) | catalogued as rs756557178; called by mutect2, varscan2
- REV3L | c.5654dup p.S1886Kfs*2 | Frame Shift Ins (INS) | VAF 16/142 reads (11%) | catalogued as rs761303551; called by mutect2, varscan2
- SEMG1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.062); catalogued as rs770232552, COSV54872445; called by muse, mutect2, varscan2
- TMEM241 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs778244273, COSV67242728; called by muse, mutect2, varscan2
- GOT1 | c.326dup p.T110Nfs*9 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- GPR179 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- HNRNPU | c.1438dup p.Q480Pfs*8 (on ENST00000283179; = p.Q542Pfs*8 on NM_004501.3) | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- PLAGL1 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 19/360 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); called by muse, mutect2
- AHNAK2 | c.3399C>T p.V1133= | Silent (SNP) | VAF 19/30 reads (63%) | catalogued as rs753134176, COSV60932296; called by muse, mutect2, varscan2
- ALDH18A1 | c.552T>A p.A184= | Silent (SNP) | VAF 25/30 reads (83%) | catalogued as COSV64662421; called by muse, mutect2, varscan2
- ESPL1 | c.216G>A p.G72= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs1239419058, COSV57758664; called by muse, mutect2, varscan2
- GMIP | c.450C>T p.Y150= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- PARD3B | c.924T>C p.G308= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV62507890; called by muse, mutect2, varscan2
- VNN1 | c.1293C>T p.F431= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs769909618, COSV63389661; called by muse, mutect2, varscan2
- ZC3H11A | c.1746G>A p.R582= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV59745584; called by muse, mutect2, varscan2
- GABRG2 | c.1249-1356G>A | Intron (SNP) | VAF 16/34 reads (47%) | catalogued as rs755430911, COSV62716923; called by muse, mutect2, varscan2
- LINC01600 | n.995C>G | RNA (SNP) | VAF 19/47 reads (40%) | called by muse, mutect2, varscan2
- TAC3 | c.292+87G>A | Intron (SNP) | VAF 24/31 reads (77%) | catalogued as rs767638274; called by muse, mutect2, varscan2
